Somatic mutation profile of tumor specimen MMRF_1846_1_BM_CD138pos (aliquot MMRF_1846_1_BM_CD138pos_T1_KBS5U_L05774) from MMRF case MMRF_1846, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.5 years (21,384 days).
Specimen MMRF_1846_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b580253-1012-4382-b960-c5939cd079dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1846_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1846_1_PB_Whole_C3_KBS5U_L05801; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05d8cce5-b091-48f9-8062-3063b46fd203

The open-access MAF lists 150 somatic variants for this specimen: 58 protein-altering or splice-affecting, 21 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, 3'UTR 43, Silent 21, Intron 15, Nonsense Mutation 5, RNA 4, 5'UTR 4, 3'Flank 3, Splice Region 2, 5'Flank 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 45/90 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CPAMD8 | c.2059G>T p.E687* (on ENST00000651564; = p.E640* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 31/94 reads (33%) | catalogued as COSV52234355, COSV99359751; called by muse, mutect2, varscan2
- DSCAML1 | c.593G>A p.R198H (on ENST00000321322; = p.R138H on NM_020693.4) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs148829010, COSV58381903, COSV58402636; called by muse, mutect2, varscan2
- EEF2K | c.1849G>T p.A617S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53784757; called by muse, mutect2, varscan2
- EPHB1 | c.922T>G p.Y308D | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV101214738; called by muse, mutect2, varscan2
- FAM205A | c.1421T>C p.L474P | Missense Mutation (SNP) | VAF 94/325 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.937); catalogued as COSV66488874; called by muse, mutect2, varscan2
- FAM83B | c.2851A>C p.S951R | Missense Mutation (SNP) | VAF 116/179 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60925184; called by muse, mutect2, varscan2
- GALNT11 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as rs368294025; called by muse, mutect2, varscan2
- GTF3C2 | c.1128-6del | Splice Region (DEL) | VAF 9/117 reads (8%) | catalogued as COSV99272562; called by mutect2, pindel
- HCN1 | c.1404A>T p.K468N | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV57498110; called by muse, mutect2, varscan2
- IGLL5 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.007); catalogued as rs1309570657; called by muse, mutect2, varscan2
- LRIT2 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.564); catalogued as rs748493791; called by muse, mutect2, varscan2
- NCKAP5 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs200754455; called by muse, mutect2
- PAPPA | c.4199C>T p.T1400I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV60294770; called by muse, mutect2, varscan2
- RRAD | c.333C>G p.F111L | Missense Mutation (SNP) | VAF 65/67 reads (97%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV100234571; called by muse, mutect2, varscan2
- SLC38A6 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs781779553; called by muse, mutect2, varscan2
- SPPL2C | c.784C>A p.L262M | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1182022665; called by muse, mutect2, varscan2
- TMEM229B | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV100664352; called by muse, mutect2, varscan2
- TREM2 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 71/238 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.476); catalogued as rs199759237; called by muse, mutect2, varscan2
- TTC34 | c.2406G>C p.Q802H | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as rs1444675188; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1773C>A p.N591K | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.013); called by muse, mutect2
- ADGRV1 | c.7914A>G p.I2638M | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- APOB | c.8182C>G p.L2728V | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- ARHGEF10 | c.244A>G p.S82G (on ENST00000398564; = p.S58G on NM_014629.4) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL9L | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- BIRC3 | c.1687A>G p.K563E | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- C16orf96 | c.2792G>T p.R931L | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CAPN11 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- CCDC178 | c.1020C>G p.Y340* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- COL24A1 | c.2990T>G p.L997R | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DNAAF4 | c.520A>T p.K174* | Nonsense Mutation (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- GPATCH8 | c.1805_1808dup p.Q604Sfs*8 | Frame Shift Ins (INS) | VAF 29/96 reads (30%) | called by mutect2, pindel, varscan2
- ICAM5 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGKC | c.182G>C p.S61T | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ITIH6 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.88); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IYD | c.363A>T p.R121S | Missense Mutation (SNP) | VAF 94/98 reads (96%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- JCAD | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- KIF15 | c.3185G>T p.C1062F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- MICALL1 | c.1172G>A p.S391N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC16 | c.12389C>T p.T4130I | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MYBL1 | c.2200A>T p.R734* | Nonsense Mutation (SNP) | VAF 96/234 reads (41%) | called by muse, mutect2, varscan2
- MYO10 | c.3556+1G>A p.X1186_splice | Splice Site (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- NRAP | c.3005A>T p.K1002M (on ENST00000359988 / NM_001322945.2; = p.K967M on NM_006175.4) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- OR52A5 | c.669A>C p.Q223H | Missense Mutation (SNP) | VAF 192/268 reads (72%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1100C>T p.T367I (on ENST00000374531 / NM_001037293.2; = p.T399I on NM_053016.6) | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.429); called by muse, mutect2
- PALM2AKAP2 | c.1944C>A p.D648E (on ENST00000259318 / NM_001136562.3; = p.D879E on NM_007203.5) | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PFN2 | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 91/146 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- PIGM | c.1250C>T p.T417I | Missense Mutation (SNP) | VAF 90/233 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3C2G | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKY | c.737A>T p.D246V | Missense Mutation (SNP) | VAF 52/63 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PTPRM | c.3520A>C p.M1174L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- SCN1B | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC22A20P | n.1403C>G | Splice Region (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- SMARCA4 | c.4639T>A p.Y1547N | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SORBS2 | c.2872T>A p.S958T (on ENST00000284776 / NM_021069.5; = p.S524T on NM_003603.6) | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- ST8SIA1 | c.655T>A p.Y219N | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TARDBP | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMPRSS15 | c.11A>T p.K4I | Missense Mutation (SNP) | VAF 19/306 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); called by muse, mutect2
- A2M | c.2283C>T p.T761= | Silent (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- AMOTL1 | c.234C>T p.N78= | Silent (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- DLG2 | c.414A>T p.A138= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99715831; called by muse, mutect2, varscan2
- DNM3 | c.666C>T p.N222= | Silent (SNP) | VAF 59/134 reads (44%) | called by muse, mutect2, varscan2
- GDA | c.906C>A p.P302= | Silent (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- IGHV3-74 | c.72G>A p.V24= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as rs751327352; called by muse, varscan2
- IRAG1 | c.756C>A p.V252= | Silent (SNP) | VAF 60/185 reads (32%) | called by muse, mutect2, varscan2
- ITPR1 | c.4056C>T p.F1352= (on ENST00000354582; = p.F1337= on NM_002222.7) | Silent (SNP) | VAF 34/165 reads (21%) | catalogued as rs763239856; called by muse, mutect2, varscan2
- KIF26A | c.891A>T p.T297= | Silent (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- L3HYPDH | c.1008A>C p.T336= | Silent (SNP) | VAF 106/220 reads (48%) | called by muse, mutect2
- NPAS2 | c.1896C>G p.S632= | Silent (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- PCDHA12 | c.1026C>T p.D342= | Silent (SNP) | VAF 59/144 reads (41%) | catalogued as COSV56513352; called by muse, mutect2, varscan2
- PDE6B | c.1233C>T p.D411= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs761301106; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIGT | c.909A>G p.T303= | Silent (SNP) | VAF 82/154 reads (53%) | catalogued as rs1422254532; called by muse, mutect2, varscan2
- PPP2R1A | c.324A>G p.A108= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- RBM12B | c.246T>A p.T82= | Silent (SNP) | VAF 89/246 reads (36%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.1206C>A p.S402= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as rs373698734; called by muse, mutect2, varscan2
- SUSD5 | c.862C>T p.L288= | Silent (SNP) | VAF 69/274 reads (25%) | catalogued as rs771822231; called by muse, mutect2, varscan2
- TTC13 | c.1029A>G p.A343= | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- USP43 | c.2073G>A p.P691= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs372302240; called by muse, mutect2, varscan2
- ZBBX | c.1050T>A p.G350= | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as COSV56788902; called by muse, mutect2, varscan2
- ABL1 | c.*86G>C | 3'UTR (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2, varscan2
- AC104452.1 | c.*600A>C | 3'UTR (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444459 T>C | 5'Flank (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- ADGRL3 | chr4:62072174 T>G | 3'Flank (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2, varscan2
- AKR1B10 | c.742-19A>T | Intron (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- APCDD1 | c.*16C>G | 3'UTR (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- APLF | c.805-2571G>A | Intron (SNP) | VAF 17/71 reads (24%) | catalogued as rs540201004; called by muse, mutect2
- ARSI | c.*202C>T | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- C21orf62 | c.*70T>C | 3'UTR (SNP) | VAF 39/160 reads (24%) | called by muse, mutect2, varscan2
- C2orf91 | n.1062G>A | RNA (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- CACNA1D | c.*970T>A | 3'UTR (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- CCDC88B | c.4306+45G>T | Intron (SNP) | VAF 59/215 reads (27%) | called by muse, mutect2, varscan2
- CDH8 | c.*1017T>A | 3'UTR (SNP) | VAF 29/29 reads (100%) | called by muse, mutect2, varscan2
- CDH8 | c.*314A>C | 3'UTR (SNP) | VAF 24/24 reads (100%) | called by muse, mutect2, varscan2
- COMMD6 | c.*863C>G | 3'UTR (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- CPNE5 | c.*5G>T | 3'UTR (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- CXCL11 | c.*177A>G | 3'UTR (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- EGFR | c.3271+14C>G | Intron (SNP) | VAF 50/151 reads (33%) | catalogued as rs772445820; called by muse, mutect2, varscan2
- EIF4G3 | c.*360A>T | 3'UTR (SNP) | VAF 21/37 reads (57%) | called by muse, mutect2, varscan2
- EOMES | c.*814A>G | 3'UTR (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- ERBB4 | c.*3023dup | 3'UTR (INS) | VAF 34/131 reads (26%) | called by mutect2, varscan2
- FAM215A | n.140G>T | RNA (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- GRIK1 | c.1207-1050A>G | Intron (SNP) | VAF 83/144 reads (58%) | called by muse, mutect2, varscan2
- HOMER1 | c.-646C>T | 5'UTR (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- HR | c.*652C>T | 3'UTR (SNP) | VAF 50/132 reads (38%) | called by muse, mutect2, varscan2
- HTR2C | c.*645G>A | 3'UTR (SNP) | VAF 25/25 reads (100%) | called by muse, mutect2, varscan2
- IGF2 | chr11:2130908 del G | 3'Flank (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- KCNT1 | c.378-57del | Intron (DEL) | VAF 24/116 reads (21%) | called by pindel, varscan2
- KLHL1 | c.-419C>T | 5'UTR (SNP) | VAF 6/78 reads (8%) | catalogued as rs962569744; called by muse, mutect2
- LARP4 | c.*1239dup | 3'UTR (INS) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- LARP7 | c.1142+366A>T | Intron (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- MAPK10 | chr4:86015306 G>T | 3'Flank (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- MEIS2 | c.*98C>G | 3'UTR (SNP) | VAF 4/83 reads (5%) | called by muse, mutect2
- MSNP1 | n.5C>T | RNA (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- NOX4 | c.*158A>C | 3'UTR (SNP) | VAF 74/264 reads (28%) | called by muse, mutect2, varscan2
- NOX5 | c.*480C>T | 3'UTR (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- NRP1 | c.-128A>T | 5'UTR (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- OPCML | c.*5035T>C | 3'UTR (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.*623A>T | 3'UTR (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- PCDH9 | c.3036+398A>C | Intron (SNP) | VAF 51/60 reads (85%) | catalogued as COSV60590133; called by muse, mutect2, varscan2
- PCDHB7 | c.*837T>G | 3'UTR (SNP) | VAF 24/174 reads (14%) | called by muse, mutect2, varscan2
- PCDHGA11 | c.2433+67T>C | Intron (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- PEX1 | c.3439-46C>G | Intron (SNP) | VAF 9/38 reads (24%) | catalogued as rs532197970; called by muse, mutect2, varscan2
- PIGQ | c.1336-112C>T | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- PPP3R1 | c.*1761C>T | 3'UTR (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2
- PSD2 | c.*1186T>C | 3'UTR (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- PXDNL | c.-82C>A | 5'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- RAB15 | c.*1917G>T | 3'UTR (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- RALYL | c.-24+797C>A | Intron (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- RBFA | c.*482T>C | 3'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- REG1B | c.433+46T>A | Intron (SNP) | VAF 36/162 reads (22%) | catalogued as COSV100521238; called by muse, mutect2, varscan2
- RFLNB | c.*146G>A | 3'UTR (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100225023; called by muse, mutect2, varscan2
- RFXAP | c.*1011A>G | 3'UTR (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- RGPD2 | c.*467C>T | 3'UTR (SNP) | VAF 105/419 reads (25%) | catalogued as rs558955521; called by muse, mutect2, varscan2
- ROR1 | c.*1496C>T | 3'UTR (SNP) | VAF 17/48 reads (35%) | catalogued as rs921267178, COSV64290935; called by muse, mutect2, varscan2
- RPS19BP1 | c.*318_*320dup | 3'UTR (INS) | VAF 42/127 reads (33%) | called by mutect2, pindel, varscan2
- SEMA5A | c.*1185T>C | 3'UTR (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- SLC25A24 | c.*249C>A | 3'UTR (SNP) | VAF 54/106 reads (51%) | called by muse, mutect2, varscan2
- SLC29A4P2 | n.989_1013del | RNA (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- SLC2A2 | c.*68C>A | 3'UTR (SNP) | VAF 75/279 reads (27%) | called by muse, mutect2, varscan2
- SOX17 | c.*811del | 3'UTR (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- SPESP1 | chr15:68930511 C>T | 5'Flank (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- SRRM4 | c.*3942A>T | 3'UTR (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- SSTR1 | c.*456G>A | 3'UTR (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- SSTR1 | c.*457G>T | 3'UTR (SNP) | VAF 46/96 reads (48%) | called by muse, mutect2, varscan2
- STEAP4 | c.*510A>C | 3'UTR (SNP) | VAF 77/128 reads (60%) | called by muse, mutect2, varscan2
- TMEM138 | c.-139-25C>T | Intron (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- TSHZ1 | c.*1140G>A | 3'UTR (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- UGT2B15 | c.*132A>G | 3'UTR (SNP) | VAF 53/125 reads (42%) | called by muse, mutect2, varscan2
- WASF3 | c.*2079G>A | 3'UTR (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- WASHC3 | c.324+141G>A | Intron (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
